Somatic mutation profile of tumor specimen TCGA-J4-A67L-01A (aliquot TCGA-J4-A67L-01A-11D-A30E-08) from TCGA case TCGA-J4-A67L, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 54.9 years (20,034 days).
Specimen TCGA-J4-A67L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f625a993-3091-4b92-a7d9-7f1375f13d65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67L-10A (Blood Derived Normal), aliquot TCGA-J4-A67L-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/041a131d-94ef-4b92-8c7c-175b11b4ceab

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQR | c.1270A>G p.M424V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV50050140; called by muse, mutect2, varscan2
- ARAP1 | c.3974G>A p.G1325E (on ENST00000393609 / NM_001040118.2; = p.G1080E on NM_015242.4) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV61994558; called by muse, mutect2, varscan2
- CD200R1L | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs191314755; called by muse, mutect2, varscan2
- DPH7 | c.546G>C p.R182S | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV53023793; called by muse, mutect2, varscan2
- GRM8 | c.2044A>G p.K682E | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.41); catalogued as COSV58862720; called by muse, mutect2
- HELZ | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs773876578, COSV62380622; called by muse, mutect2, varscan2
- HK3 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.02); catalogued as rs201695375, COSV52842187; called by muse, mutect2
- METRN | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54799857; called by muse, mutect2, varscan2
- NIBAN2 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.082); catalogued as COSV64825416; called by muse, mutect2, varscan2
- NRXN3 | c.3080G>A p.R1027H (on ENST00000335750 / NM_001330195.2; = p.R654H on NM_004796.6) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368490229; called by muse, mutect2, varscan2
- NUP205 | c.3355A>G p.T1119A | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as rs1406446167, COSV53665347; called by muse, mutect2, varscan2
- PLXNB1 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs755602385, COSV56488361; called by muse, mutect2, varscan2
- RBBP6 | c.600G>C p.M200I | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV60508205; called by muse, mutect2, varscan2
- SDCBP | c.527A>T p.K176M | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52707369; called by muse, mutect2, varscan2
- ST8SIA1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 19/102 reads (19%) | catalogued as COSV53958557; called by muse, mutect2, varscan2
- UTRN | c.5900G>A p.R1967Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1043522261, COSV62332209, COSV62347377; called by muse, mutect2, varscan2
- ZC3H18 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV56327679; called by muse, mutect2, varscan2
- ZFP37 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.569); catalogued as rs200826735, COSV65285929; called by muse, mutect2, varscan2
- ZNF253 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63038450; called by muse, mutect2
- ZNF528 | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV64621007; called by muse, mutect2, varscan2
- ZNF827 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | catalogued as rs1350256977, COSV65231248; called by muse, mutect2, varscan2
- ADCY10 | c.2253T>G p.V751= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV63244414; called by muse, mutect2, varscan2
- CD1E | c.570C>T p.C190= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs753931697, COSV63772676; called by muse, mutect2, varscan2
- EXOSC9 | c.213A>C p.A71= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs1449563592, COSV54667800; called by muse, mutect2, varscan2
- FOXD4L4 | c.204G>A p.A68= | Silent (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- FOXD4L5 | c.204G>A p.A68= | Silent (SNP) | VAF 18/243 reads (7%) | catalogued as rs762262426, COSV101072986; called by muse, mutect2
- PCDHA6 | c.1701G>A p.A567= | Silent (SNP) | VAF 41/246 reads (17%) | catalogued as rs782043598, COSV65347018; called by muse, mutect2, varscan2
- ZC3H18 | c.1521G>C p.P507= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV56327669; called by mutect2, varscan2
- CCDC18 | c.-3+377C>G | Intron (SNP) | VAF 16/81 reads (20%) | catalogued as COSV58147143; called by muse, mutect2, varscan2
- EIF4A1 | c.515-112T>G | Intron (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99549206; called by muse, mutect2, varscan2
- SSPOP | n.10030C>T | RNA (SNP) | VAF 22/84 reads (26%) | catalogued as COSV65136335; called by muse, mutect2, varscan2
